Somatic mutation profile of tumor specimen TCGA-B0-5699-01A (aliquot TCGA-B0-5699-01A-11D-1534-10) from TCGA case TCGA-B0-5699, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 53.8 years (19,647 days).
Specimen TCGA-B0-5699-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ffc1e106-b286-453e-a632-25923c2cb123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B0-5699-11A (Solid Tissue Normal), aliquot TCGA-B0-5699-11A-01D-1534-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3b6794ce-5242-4efa-badf-9c92924be5fa

The open-access MAF lists 45 somatic variants for this specimen: 33 protein-altering or splice-affecting, 11 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 24, Silent 11, Splice Site 4, Nonsense Mutation 3, Frame Shift Del 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A1CF | c.241A>T p.K81* | Nonsense Mutation (SNP) | VAF 89/297 reads (30%) | catalogued as COSV50988505; called by muse, mutect2, varscan2
- ABCB1 | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 39/142 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55953442; called by muse, mutect2, varscan2
- ALDH1L1 | c.1393G>C p.V465L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as COSV56416936; called by muse, mutect2, varscan2
- ANKRD27 | c.1939T>A p.S647T | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.161); catalogued as COSV60133998; called by muse, mutect2, varscan2
- ARHGAP5 | c.3465T>G p.Y1155* | Nonsense Mutation (SNP) | VAF 34/89 reads (38%) | catalogued as COSV61537950; called by muse, mutect2, varscan2
- CLEC2L | c.398C>A p.A133E | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV70691409; called by muse, mutect2, varscan2
- COL9A2 | c.452C>T p.P151L | Missense Mutation (SNP) | VAF 24/55 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); catalogued as COSV65607845; called by muse, varscan2
- DCAF11 | c.714G>C p.W238C | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58108318, COSV58109990; called by muse, mutect2, varscan2
- DCST1 | c.85G>T p.G29W | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.628); catalogued as rs1302485734, COSV55053266; called by muse, mutect2
- DDX27 | c.202G>C p.G68R | Missense Mutation (SNP) | VAF 41/128 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.05); catalogued as COSV100874713, COSV65630525; called by muse, mutect2, varscan2
- EYA2 | c.580C>A p.P194T | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.18); PolyPhen benign (0.321); catalogued as COSV57947672; called by muse, mutect2, varscan2
- FAM71B | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as rs1291697774, COSV57230115; called by muse, mutect2, varscan2
- FPR1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 13/57 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0.019); catalogued as rs547228145, COSV59053059; called by muse, mutect2, varscan2
- GATA5 | c.805C>T p.L269F | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53346886; called by muse, mutect2
- GSR | c.1367A>G p.K456R | Missense Mutation (SNP) | VAF 217/597 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV55322051, COSV99645866; called by muse, mutect2, varscan2
- NAT9 | c.190+2T>C p.X64_splice | Splice Site (SNP) | VAF 16/52 reads (31%) | catalogued as rs1567842723, COSV52854203; called by muse, mutect2
- NAV2 | c.1522A>T p.N508Y (on ENST00000396087 / NM_001244963.2; = p.N485Y on NM_145117.5) | Missense Mutation (SNP) | VAF 55/176 reads (31%) | SIFT deleterious (0.03); PolyPhen benign (0.429); catalogued as COSV62328939; called by muse, mutect2, varscan2
- NOP14 | c.1635+2T>C p.X545_splice | Splice Site (SNP) | VAF 33/86 reads (38%) | catalogued as COSV58626581; called by muse, mutect2, varscan2
- PBRM1 | c.1840C>G p.L614V | Missense Mutation (SNP) | VAF 49/94 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56290583; called by muse, mutect2, varscan2
- PCDHGB4 | c.2273G>C p.G758A | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT tolerated (0.73); PolyPhen benign (0.007); catalogued as COSV53993504; called by muse, mutect2, varscan2
- PRDM9 | c.569C>A p.A190E | Missense Mutation (SNP) | VAF 42/164 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.022); catalogued as COSV57010346; called by muse, mutect2, varscan2
- PTK2B | c.1817G>A p.S606N | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV57761596, COSV57765115; called by muse, mutect2, varscan2
- RPL3 | c.962T>A p.V321D | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); catalogued as COSV53366115; called by muse, mutect2, varscan2
- SCAF4 | c.169G>C p.E57Q | Missense Mutation (SNP) | VAF 53/143 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54590110; called by muse, mutect2, varscan2
- SETD2 | c.1628C>A p.S543* | Nonsense Mutation (SNP) | VAF 66/125 reads (53%) | catalogued as COSV57445121; called by muse, mutect2, varscan2
- SYT1 | c.850G>A p.V284I | Missense Mutation (SNP) | VAF 100/289 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.08); catalogued as COSV54062037; called by muse, mutect2, varscan2
- UGT2B11 | c.754A>G p.K252E | Missense Mutation (SNP) | VAF 135/412 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); catalogued as COSV71423783; called by muse, mutect2, varscan2
- UGT2B4 | c.1311-1G>C p.X437_splice | Splice Site (SNP) | VAF 20/103 reads (19%) | catalogued as rs71599906, COSV59318909; called by muse, mutect2, varscan2
- VAV1 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58388012; called by muse, mutect2, varscan2
- ZNF740 | c.300T>A p.N100K | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV69664679; called by muse, mutect2, varscan2
- ATP2B1 | c.3169-10_3185del p.X1057_splice | Splice Site (DEL) | VAF 52/233 reads (22%) | called by mutect2, pindel
- BAP1 | c.2132del p.K711Sfs*25 | Frame Shift Del (DEL) | VAF 6/7 reads (86%) | called by mutect2, varscan2
- FAM83G | c.1967_1973dup p.F659Rfs*53 | Frame Shift Ins (INS) | VAF 10/31 reads (32%) | called by mutect2, varscan2
- ACSBG1 | c.378C>T p.R126= | Silent (SNP) | VAF 55/116 reads (47%) | catalogued as COSV51908792; called by muse, mutect2, varscan2
- EHBP1 | c.21A>G p.R7= | Silent (SNP) | VAF 43/150 reads (29%) | catalogued as COSV50428290; called by muse, mutect2, varscan2
- GJB3 | c.249C>T p.F83= | Silent (SNP) | VAF 60/137 reads (44%) | catalogued as COSV64904451; called by muse, mutect2, varscan2
- HSPA8 | c.459T>C p.S153= | Silent (SNP) | VAF 31/74 reads (42%) | catalogued as COSV57085091; called by muse, mutect2, varscan2
- NAV2 | c.1521C>A p.G507= (on ENST00000396087 / NM_001244963.2; = p.G484= on NM_145117.5) | Silent (SNP) | VAF 55/174 reads (32%) | catalogued as COSV62328936; called by muse, mutect2, varscan2
- PCMT1 | c.342A>G p.Q114= | Silent (SNP) | VAF 111/331 reads (34%) | catalogued as COSV66303770; called by muse, mutect2, varscan2
- RELCH | c.147T>G p.P49= | Silent (SNP) | VAF 20/56 reads (36%) | catalogued as COSV56888969; called by muse, mutect2
- SLC26A8 | c.2220C>T p.V740= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as rs193054248, COSV62886061, COSV62886866; called by muse, mutect2, varscan2
- SYNGAP1 | c.1719G>A p.R573= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as rs938711998, COSV53384607; called by muse, mutect2, varscan2
- VCPKMT | c.615A>G p.K205= | Silent (SNP) | VAF 74/229 reads (32%) | catalogued as COSV53571134; called by muse, mutect2, varscan2
- ZNFX1 | c.399G>A p.K133= | Silent (SNP) | VAF 14/40 reads (35%) | catalogued as COSV65577157; called by muse, mutect2, varscan2
- ADD3 | c.-2A>G | 5'UTR (SNP) | VAF 4/50 reads (8%) | catalogued as COSV99523774; called by muse, mutect2
